Somatic mutation profile of tumor specimen TCGA-OY-A56P-01A (aliquot TCGA-OY-A56P-01A-12D-A403-09) from TCGA case TCGA-OY-A56P, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.1 years (17,580 days).
Specimen TCGA-OY-A56P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e887db8d-cd20-489e-990d-f36c36029d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OY-A56P-10A (Blood Derived Normal), aliquot TCGA-OY-A56P-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ce76ae-6226-4f5a-9bd6-8ba870537770

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 29/29 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARC | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV63079251; called by muse, mutect2
- CCDC12 | c.373G>C p.E125Q (on ENST00000425441 / NM_001277074.1; = p.E138Q on NM_144716.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV99438889; called by muse, mutect2, varscan2
- COL4A2 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.121); catalogued as rs779357792, COSV64627571; called by mutect2, varscan2
- COPS2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100157244; called by muse, mutect2, varscan2
- DDC | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs142925706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EWSR1 | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100131401, COSV58421820; called by muse, mutect2, varscan2
- FMNL2 | c.3239A>G p.Q1080R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs773739366, COSV99979655; called by muse, mutect2, varscan2
- HYOU1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs782759376, COSV68216872; called by muse, mutect2
- KHDRBS2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs374827571; called by muse, mutect2, varscan2
- MCM4 | c.1431G>C p.K477N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031536; called by muse, mutect2, varscan2
- MROH5 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs749646876, COSV101435992; called by mutect2, varscan2
- MROH7 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59871765, COSV59877281; called by muse, mutect2, varscan2
- PGAP1 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.025); catalogued as COSV100698187; called by muse, mutect2, varscan2
- PSG4 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV54936835, COSV99737048; called by muse, mutect2, varscan2
- SRRM2 | c.5803T>C p.S1935P | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100070766; called by muse, mutect2, varscan2
- SUSD4 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs147477935; called by muse, mutect2, varscan2
- TNR | c.2710G>C p.G904R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99686642, COSV99689544; called by muse, mutect2, varscan2
- WDR49 | c.1649A>G p.E550G (on ENST00000308378 / NM_001366158.1; = p.E891G on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/149 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100392732, COSV57711209; called by muse, mutect2, varscan2
- ZBED8 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs114816914; called by muse, mutect2, varscan2
- ZCWPW1 | c.1517T>A p.L506Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV52201096, COSV99546486; called by muse, mutect2
- DLGAP2 | c.2615del p.L872* | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- B3GNTL1 | c.648C>T p.G216= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs375983406; called by muse, mutect2, varscan2
- HEATR5B | c.2950T>C p.L984= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99249279; called by muse, mutect2
- IMMT | c.1413C>T p.V471= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs1170808184, COSV99607284; called by muse, mutect2, varscan2
- MACC1 | c.1038A>G p.L346= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100255800; called by muse, mutect2, varscan2
- MYC | c.750C>T p.S250= (on ENST00000377970; = p.S265= on NM_002467.6) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV104388352, COSV99420376; called by muse, mutect2, varscan2
- NRAP | c.4635C>T p.I1545= (on ENST00000359988 / NM_001322945.2; = p.I1510= on NM_006175.4) | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs750434227, COSV63490474; called by muse, mutect2, varscan2
- TSSK3 | c.270C>T p.L90= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs749142392, COSV100344744; called by muse, mutect2, varscan2
